Somatic mutation profile of tumor specimen ffc76bfb-61f6-4492-a782-c23321 (aliquot ffc76bfb-61f6-4492-a782-c23321_D6) from CPTAC case 05BR003, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 37.6 years (13,717 days).
Specimen ffc76bfb-61f6-4492-a782-c23321: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 616839a1-2e53-47c4-8fec-bb1e1d92dc78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen e18f4e63-342f-4b53-9236-e1b4e3 (Blood Derived Normal), aliquot e18f4e63-342f-4b53-9236-e1b4e3_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5de9cd68-d542-449c-8bf7-85dc537dd7ba

The open-access MAF lists 32 somatic variants for this specimen: 24 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, 3'UTR 3, Silent 3, Nonsense Mutation 2, 5'Flank 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APBA1 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs772591680, COSV55227556; called by muse, mutect2, varscan2
- AUTS2 | c.2813G>A p.R938Q | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.588); catalogued as rs761448632; called by muse, mutect2
- C5AR2 | c.56G>T p.R19L | Missense Mutation (SNP) | VAF 153/611 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs150108068, COSV57256464; called by mutect2, varscan2
- CACNA1F | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 24/762 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1436373432; called by muse, mutect2
- CSTF1 | c.1283C>T p.S428L | Missense Mutation (SNP) | VAF 35/313 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs865777609, COSV99410225; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 57/319 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs892572688; called by muse, mutect2, varscan2
- LHX8 | c.955G>C p.D319H | Missense Mutation (SNP) | VAF 38/336 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV53960151; called by muse, mutect2, varscan2
- RAD54L | c.1637C>T p.T546M | Missense Mutation (SNP) | VAF 74/288 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1361241713; called by muse, mutect2, varscan2
- SLC25A47 | c.144+1G>A p.X48_splice | Splice Site (SNP) | VAF 42/132 reads (32%) | catalogued as rs367820954, COSV100836458, COSV64161427; called by muse, mutect2, varscan2
- SLC38A2 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.494); catalogued as rs1167493484; called by muse, mutect2
- TAS2R30 | c.772C>T p.Q258* | Nonsense Mutation (SNP) | VAF 53/395 reads (13%) | catalogued as COSV67855939; called by muse, mutect2, varscan2
- AGO3 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- BIRC3 | c.740T>C p.V247A | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C12orf50 | c.327T>G p.I109M | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CELF2 | c.152G>A p.W51* (on ENST00000416382 / NM_001025077.3; = p.W58* on NM_006561.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 31/99 reads (31%) | called by muse, mutect2, varscan2
- EPM2AIP1 | c.452G>A p.R151K | Missense Mutation (SNP) | VAF 104/448 reads (23%) | SIFT tolerated (0.9); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ERVV-2 | c.1240G>T p.G414W | Missense Mutation (SNP) | VAF 43/310 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FITM2 | c.268G>C p.V90L | Missense Mutation (SNP) | VAF 90/528 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.063); called by mutect2, varscan2
- KDM4A | c.2579G>A p.C860Y | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PTPN13 | c.3793T>A p.F1265I (on ENST00000411767 / NM_080683.3; = p.F1246I on NM_006264.3) | Missense Mutation (SNP) | VAF 29/386 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.079); called by muse, mutect2
- REPS1 | c.1278A>T p.E426D | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- SNX31 | c.467T>C p.L156P | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TLL2 | c.892A>T p.I298F | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UBR4 | c.221A>G p.Y74C | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CCDC146 | c.2577G>C p.L859= | Silent (SNP) | VAF 65/342 reads (19%) | called by muse, mutect2, varscan2
- DOP1A | c.4123T>C p.L1375= | Silent (SNP) | VAF 76/242 reads (31%) | catalogued as COSV99382423; called by muse, mutect2, varscan2
- OR51M1 | c.504T>A p.T168= | Silent (SNP) | VAF 311/836 reads (37%) | called by muse, mutect2, varscan2
- ATP2B2 | c.*243C>G | 3'UTR (SNP) | VAF 77/376 reads (20%) | called by muse, mutect2, varscan2
- DCAF17 | c.*2677T>A | 3'UTR (SNP) | VAF 28/365 reads (8%) | called by muse, mutect2
- LRRK2 | c.3496+1582G>T | Intron (SNP) | VAF 41/212 reads (19%) | called by muse, mutect2, varscan2
- ORC4 | c.*17C>A | 3'UTR (SNP) | VAF 71/342 reads (21%) | called by muse, mutect2, varscan2
- RAD21 | chr8:116875466 G>T | 5'Flank (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
